EXCEPTIONAL_RESPONDERS case ER-AE8U — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/70e7a4c9-255d-4854-af74-54dca40839c5

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1936; Vital status: Dead; Days to death: 497 days (1.4 years); Year of death: 2013.

Diagnoses (1)
1. Clear cell carcinoma: ICD-O-3 morphology code: 8310/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Classification of tumor: metastasis; Age at diagnosis: 76.1 years (27,796 days); Year of diagnosis: 2012; Prior malignancy: no; Days to last follow up: 426 days (1.2 years); Days to best overall response: 91 days; Best overall response: Partial Response.
   Treatment given: Therapeutic agents: Temsirolimus; Days to treatment start: 29 days; Days to treatment end: 471 days (1.3 years).

Follow-up (1 entry)
- Days to follow up: 426 days (1.2 years); Disease response: Clinical Progression; Progression or recurrence: Yes; Days to progression: 426 days (1.2 years); Days to recurrence: 0 days.

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-AE8U-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-AE8U-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 30; Percent tumor nuclei: 40; Percent normal cells: 0; Percent necrosis: 30; Percent stromal cells: 40; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
